Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3975, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3975-01A (Primary Tumor).

This is an invasive, moderately differentiated adenocarcinoma of the colon (G2) with infiltration of the muscularis (pT2) without vascular infiltration (L0, V0).

Tumor classification:

ICDO-DA-M 8140/3

G2

pT2, L0, V0

pN0 (0 of 14)

locally R0

M classification in the context of an oncology conference

Source: NCI Genomic Data Commons file a665591d-3fb3-4a8d-b6e9-70bb4000d431 (TCGA-AA-3975.2EA60AAB-1F16-4DD6-9F73-39103A726D83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).